Gene-level copy-number profile of tumor specimen TCGA-91-6831-01A from TCGA case TCGA-91-6831, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 66.9 years (24,436 days).
Specimen TCGA-91-6831-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.3646baa9-08e0-48c0-8e23-31b6f0e64863.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-91-6831-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1a596366-001f-442c-9623-b40a5d18193f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 129; copy number 2: 16,227; copy number 3: 16,889; copy number 4: 15,506; copy number 5: 8,053; copy number 6: 697; copy number 7: 1,514; copy number 8: 414; copy number 9: 13; copy number 10: 5; copy number 11: 81; copy number 12: 73; copy number 15: 6; copy number 17: 44; copy number 18: 32; copy number 21: 17; copy number 28: 11; copy number 35: 15; copy number 46: 15; copy number 47: 39; copy number 58: 1; copy number 96: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-91-6831-01A-11D-1854-01): tumor purity 0.5, ploidy 3.3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–5): MTAP, AL359922.1.
- chr9:21,858,910–22,824,213, 14 genes (within-gene range 0–5): AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,289 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:40,415,137–40,984,643, 14 genes, copy number 10–28: AC093277.1, AC114977.1, AC114977.2, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1.
- chr7:70,972–62,275,678, 1,079 genes, copy number 7 (broad region; genes not listed).
- chr8:5,363,371–5,509,126, 4 genes, copy number 7: AC007718.1, AC091193.1, RPL23AP54, AC004944.1.
- chr8:12,467,693–12,665,588, 1 gene, copy number 7 (within-gene range 2–7): AC068587.4.
- chr8:12,570,350–14,023,422, 35 genes, copy number 7: RPS3AP34, AC068587.2, AC068587.8, AC068587.6, RPS3AP35, AC068587.3, AC068587.7, AC068587.5, AC068587.1, OR7E8P, OR7E15P, OR7E10P, MIR5692A2, LONRF1, MIR3926-1, MIR3926-2, AC123777.1, LINC00681, TRMT9B, AC135352.1, RNU6-842P, DLC1, AC106845.1, Y_RNA, AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1, AC022832.2, AC022880.2, AC022880.1, AC022690.2, AC022690.1, AC023538.1.
- chr8:14,161,084–14,487,879, 5 genes, copy number 7: AC022039.1, EIF4EP5, RNU7-153P, Y_RNA, RNU6-397P.
- chr8:15,417,215–17,570,573, 26 genes, copy number 7 (within-gene range 5–7): TUSC3, AC100850.1, PPM1AP1, AC018437.3, AC018437.1, AC018437.2, MSR1, CCT3P1, MRPL49P2, AC011586.2, AC011586.1, RN7SL474P, FGF20, MICU3, AC079193.2, AC079193.1, ZDHHC2, CNOT7, VPS37A, MTMR7, ADAM24P, SLC7A2, AP006248.2, AP006248.4, SLC7A2-IT1, AP006248.3.
- chr8:17,596,312–17,596,378, 1 gene, copy number 7: AP006248.1.
- chr8:37,326,575–40,016,391, 80 genes, copy number 8–35 (broad region; genes not listed).
- chr8:60,046,755–63,609,600, 52 genes, copy number 7: AC021393.1, SLC2A13P1, CA8, LINC01301, PDCL3P1, RAB2A, AC068389.3, AC068389.1, AC068389.2, CHD7, AC113143.1, AC113143.2, IFITM3P8, AC022182.1, NASPP1, AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1, ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3, NARS1P2, AC104852.1, AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P, AC011124.1, IFITM8P, AC011124.2, AC018953.1, RN7SKP135.
- chr10:34,663,859–36,089,389, 30 genes, copy number 8: RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, LINC02635, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5, LINC02630, AL355300.1.
- chr11:65,066,300–88,524,054, 690 genes, copy number 7–12 (broad region; genes not listed).
- chr12:64,759,484–71,032,083, 129 genes, copy number 9–58 (within-gene range 4–58) (broad region; genes not listed).
- chr12:73,648,666–74,402,600, 11 genes, copy number 10–96: AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3.
- chr20:41,024,205–41,366,818, 12 genes, copy number 7: RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81, RN7SL615P, ADI1P1, LPIN3, EMILIN3.
- chr20:49,920,597–51,131,667, 41 genes, copy number 7–11: Y_RNA, Metazoa_SRP, RNF114, KRT18P4, RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645, RIPOR3, MIR1302-5, RPL36P2, RIPOR3-AS1, PARD6B, BCAS4, TMSB4XP6, ADNP, PSMD10P1, ADNP-AS1, DPM1, MOCS3, AL050404.1, KCNG1, AL121785.1, RPSAP1.
- chr20:53,453,058–54,651,169, 17 genes, copy number 8–12: AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5.
- chr20:61,953,469–62,065,810, 1 gene, copy number 8 (within-gene range 3–8): TAF4.
- chr20:62,037,429–63,129,459, 61 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 129. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
